TCGA case TCGA-86-8673 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc4c4079-b449-485d-84e4-a40496e563e8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Bronchiolo-alveolar carcinoma, non-mucinous (the primary disease): ICD-O-3 morphology code: 8252/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.8 years (22,571 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
2. Recurrence of diagnosis 1 (Bronchiolo-alveolar carcinoma, non-mucinous). Age at diagnosis: 63.5 years (23,207 days); Days to diagnosis: 636 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 639 days (1.7 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Days to follow up: 455 days (1.2 years); Disease response: Tumor Free.
- Day 636 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 636 days (1.7 years).
- Days to follow up: 862 days (2.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 54; Tobacco smoking onset year: 1968.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-86-8673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.9; Intermediate dimension: 1.8; Shortest dimension: 0.5.
  Slide TCGA-86-8673-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-86-8673-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 2; Percent lymphocyte infiltration: 17; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
- Sample TCGA-86-8673-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-86-8673-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Bronchioloalveolar Carcinoma Nonmucinous; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 862 days; disease-specific survival: no event (censored), 862 days; disease-free interval: event (new tumor event after initially disease-free), 636 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 636 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-86-8673-01A-11D-2389-01): tumor purity 0.4, ploidy 2.56, whole-genome doublings 1.
